Somatic mutation profile of tumor specimen C3N-02768-01 (aliquot CPT0207980008) from CPTAC case C3N-02768, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.6 years (17,037 days).
Specimen C3N-02768-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 212d865c-f38c-4932-8fb4-9f433cd3d885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02768-71 (Blood Derived Normal), aliquot CPT0208030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6325e4a0-27dc-4e50-a254-ba318c282095

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Intron 5, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 158/512 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 108/395 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs779937883, COSV100719479; called by muse, mutect2, varscan2
- ACSL3 | c.666+1G>A p.X222_splice | Splice Site (SNP) | VAF 23/75 reads (31%) | catalogued as rs191324442; called by mutect2, varscan2
- ACVR1B | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57777072; called by muse, mutect2, varscan2
- ATP2B4 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 71/697 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778946356; called by muse, mutect2, varscan2
- BACH2 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57588264; called by muse, mutect2, varscan2
- BCL9L | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs147776799; called by muse, mutect2, varscan2
- CTDSPL | c.267+1G>A p.X89_splice | Splice Site (SNP) | VAF 43/318 reads (14%) | catalogued as rs200957541; called by mutect2, varscan2
- DNAAF3 | c.712G>A p.V238I (on ENST00000524407 / NM_001256715.2; = p.V285I on NM_178837.4) | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as rs1380206004, COSV100788022; ClinVar: uncertain significance; called by muse, mutect2
- DNAH9 | c.7436C>T p.T2479M | Missense Mutation (SNP) | VAF 204/877 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs546685970, COSV52334403; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- HCN4 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56086245; called by muse, mutect2, varscan2
- HECW1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 55/592 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs770727253, COSV67836527; called by muse, mutect2
- HSPB8 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 202/845 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs1343984954, COSV56139133; called by muse, mutect2, varscan2
- IBA57 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV64511631; called by muse, mutect2, varscan2
- KRT71 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 56/548 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1199957918; called by muse, mutect2, varscan2
- MIDEAS | c.106dup p.Q36Pfs*33 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | catalogued as rs760940567; called by mutect2, varscan2
- MLLT1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1462618748; called by muse, mutect2
- PEX11G | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs774587572; called by muse, mutect2, varscan2
- PPFIA3 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773800064, COSV61952960; called by muse, mutect2, varscan2
- PRKCG | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 48/492 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as rs1416084216; called by muse, mutect2
- RERE | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 67/500 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1465785398; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.549C>A p.N183K | Missense Mutation (SNP) | VAF 128/505 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs541989724, COSV53448035; called by muse, mutect2, varscan2
- SCN9A | c.2248del p.I750Lfs*5 (on ENST00000303354; = p.I739Lfs*5 on NM_002977.3) | Frame Shift Del (DEL) | VAF 46/223 reads (21%) | catalogued as CM0910318; called by mutect2, pindel, varscan2
- SIN3A | c.3266C>T p.S1089L | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs929890594; called by muse, mutect2, varscan2
- TMEM121 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 120/561 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs1189287802, COSV66796086; called by muse, mutect2, varscan2
- TMEM151A | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 72/768 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59174702; called by muse, mutect2
- UMOD | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 107/599 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1280804618; called by muse, mutect2, varscan2
- ZNF248 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 24/557 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100627698; called by muse, mutect2
- CHD5 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EFCAB5 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- EFCAB5 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EFCAB5 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 82/575 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- EPPK1 | c.5963C>G p.P1988R | Missense Mutation (SNP) | VAF 45/423 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GRIK1 | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 53/443 reads (12%) | called by muse, mutect2, varscan2
- ITIH2 | c.1580T>C p.I527T | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, varscan2
- KATNBL1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 54/442 reads (12%) | called by muse, mutect2, varscan2
- KIAA0895 | c.1468C>T p.H490Y (on ENST00000297063 / NM_001100425.2; = p.H439Y on NM_015314.3) | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- MUC12 | c.15472G>T p.E5158* (on ENST00000379442; = p.E5015* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- N4BP2 | c.2261A>G p.E754G | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NCKIPSD | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- SCN9A | c.5738C>T p.S1913L (on ENST00000303354; = p.S1902L on NM_002977.3) | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- SEMA6B | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SLITRK6 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SPTAN1 | c.6580C>T p.Q2194* | Nonsense Mutation (SNP) | VAF 89/268 reads (33%) | called by muse, mutect2, varscan2
- SSH3 | c.1428G>A p.W476* | Nonsense Mutation (SNP) | VAF 72/219 reads (33%) | called by muse, mutect2, varscan2
- TFAP2C | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132B | c.2371C>A p.P791T | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.232); called by muse, mutect2
- TMEM176B | c.470_486del p.F157Cfs*3 | Frame Shift Del (DEL) | VAF 90/999 reads (9%) | called by mutect2, pindel
- USH2A | c.9055+1G>T p.X3019_splice | Splice Site (SNP) | VAF 71/692 reads (10%) | called by muse, mutect2, varscan2
- ZNF775 | c.1022A>T p.H341L | Missense Mutation (SNP) | VAF 93/938 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2
- DNAH11 | c.2382G>A p.E794= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV60984471; called by muse, mutect2
- FAM90A26 | c.189C>T p.C63= | Silent (SNP) | VAF 121/490 reads (25%) | called by muse, mutect2, varscan2
- GGTLC1 | c.291T>C p.N97= | Silent (SNP) | VAF 63/487 reads (13%) | called by muse, mutect2, varscan2
- IL16 | c.2070G>A p.P690= | Silent (SNP) | VAF 29/273 reads (11%) | catalogued as rs775632260; called by muse, mutect2, varscan2
- KCNQ2 | c.2328C>T p.P776= (on ENST00000359125 / NM_172107.4; = p.P748= on NM_004518.6) | Silent (SNP) | VAF 66/326 reads (20%) | called by muse, mutect2
- NEO1 | c.2238C>T p.H746= | Silent (SNP) | VAF 45/205 reads (22%) | catalogued as rs148124514; called by muse, mutect2, varscan2
- PCDHA6 | c.1812C>T p.N604= | Silent (SNP) | VAF 222/962 reads (23%) | catalogued as rs782134190; called by muse, mutect2, varscan2
- PPP4R3C | c.795G>A p.Q265= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- RIPK4 | c.2454C>T p.G818= (on ENST00000352483; = p.G770= on NM_020639.3) | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs767725466, COSV100205401; called by mutect2, varscan2
- RTL1 | c.312C>T p.N104= | Silent (SNP) | VAF 59/359 reads (16%) | catalogued as rs370765201; called by muse, mutect2, varscan2
- SERPINI2 | c.924C>T p.T308= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as rs140665807; called by muse, mutect2, varscan2
- TBPL1 | c.363A>G p.T121= | Silent (SNP) | VAF 32/215 reads (15%) | called by muse, mutect2, varscan2
- TRIML1 | c.1149C>T p.I383= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as rs758081985, COSV60193621; called by muse, mutect2, varscan2
- CTSA | c.194+24G>A | Intron (SNP) | VAF 89/865 reads (10%) | catalogued as rs753979268; called by muse, mutect2, varscan2
- PLA2G15 | c.285-1419G>A | Intron (SNP) | VAF 12/178 reads (7%) | catalogued as rs997402134; called by muse, mutect2
- RIPOR2 | c.1921-364T>G | Intron (SNP) | VAF 16/145 reads (11%) | catalogued as rs776550242; called by muse, mutect2, varscan2
- SLC12A3 | c.2721-9C>T | Intron (SNP) | VAF 122/580 reads (21%) | catalogued as rs1489717334; called by muse, varscan2
- ZNF726 | c.226+58A>G | Intron (SNP) | VAF 58/243 reads (24%) | called by muse, mutect2, varscan2
